Somatic mutation profile of tumor specimen TARGET-20-PANJGR-09A (aliquot TARGET-20-PANJGR-09A-03D) from TARGET case TARGET-20-PANJGR, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 12.1 years (4,425 days).
Specimen TARGET-20-PANJGR-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d44fbda0-a437-48f7-963c-2888a7e7dce0.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PANJGR-14A (Bone Marrow Normal), aliquot TARGET-20-PANJGR-14A-02D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/70dd1d2e-f4f9-4a17-a6b9-4c2bfefd9d54

The open-access MAF lists 4 somatic variants for this specimen: 3 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: In Frame Del 1, 3'UTR 1, Frame Shift Ins 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ETV6 | c.274_286del p.K92Cfs*2 | Frame Shift Del (DEL) | VAF 51/150 reads (34%) | called by mutect2, pindel, varscan2
- IKZF1 | c.576_577insGG p.R193Gfs*25 | Frame Shift Ins (INS) | VAF 33/92 reads (36%) | called by mutect2, pindel, varscan2
- KIT | c.1255_1257del p.D419del | In Frame Del (DEL) | VAF 66/176 reads (38%) | called by mutect2, pindel, varscan2
- FAT1 | c.*468A>G | 3'UTR (SNP) | VAF 13/167 reads (8%) | called by muse, mutect2
